Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A3EK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A3EK-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO:

Pre-Op Diagnosis
Endometrial cancer
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Five parts

Container labeled "1 - right pelvic lymph node" has 6.0 x 4.5 x 1.6 cm of tan-yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined pink-yellow nodules up to 2.0 cm. The largest nodules are bisected and submitted labeled A-B. Whole smaller nodules are submitted labeled C.

Container labeled "2 - left pelvic lymph node" has 4.7 x 4.0 x 2.0 cm of tan-yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined pink-yellow nodules up to 2.1 cm. The largest nodule is bisected and submitted labeled A. Whole smaller nodules are submitted labeled B-C.

Container labeled "3 - right aortic lymph node" has 3.2 x 2.0 x 1.0 cm of tan-yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined pink-yellow nodules up to 1.9 cm. The nodules are entirely submitted in two cassettes.

Container labeled "4 - left aortic lymph node" has 4.0 x 3.1 x 1.1 cm of tan-yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined pink-yellow nodules up to 1.6 cm. The largest nodule is bisected and submitted

ICD-0-3
adenocarcinoma, mixed endometrioid
8441/3
and serous - code to highest (8441/3)
Site: Endometrium 1541

1/16/12

page 1 of 4

[page 2 of 4]
labeled A. Whole smaller nodules are submitted labeled B.

Container labeled "5 - uterus, cervix, tubes and ovaries" has a previously laterally opened moderately distorted uterus with attached cervix and bilateral adnexa. The uterus and cervix together weigh 96 grams and on reconstruction measure approximately 9.1 x 5.6 x 4.2 cm. The cervix has a wrinkled tan-pink ectocervical mucosa. The os is patent. The uterine canal sounds to a depth of 6.5 cm. The endocervical canal is lined by trabeculated tan-pink mucosa. The uterine serosa is smooth and tan-pink. The myometrium measures up to 1.6 cm and is tan-pink and fibrotic. Virtually the entire endometrial canal is occupied by a friable gray-tan to pink papilliferous plaque-like lesion occupying both the anterior and posterior aspects extending to both lateral aspects and the fundus, as well as into the lower uterine segment. This occupies an area of approximately 8.8 x 3.5 cm. On the posterior aspect this measures up to 0.7 cm in thickness and grossly appears to focally extend into the wall. In the right lateral aspect the lesion grossly appears to focally extend to within 1.1 cm of the outer surface margin. The parametrial soft tissue on each side shows no nodularity or gross lesion. The left fallopian tube measures 6.1 x 0.5 x 0.5 cm. The right fallopian tube measures 5.9 x 0.5 x 0.5 cm. Each has a smooth tan-pink serosa with a tan-pink wall and a pinpoint lumen. The left ovary measures 3.1 x 2.1 x 1.6 cm and has a lobular tan-yellow outer surface with a mottled tan-gray fibrotic cut surface. The right ovary measures 3.6 x 1.6 x 1.0 cm and has a lobular tan-yellow outer surface with a mottled tan-gray to pink fibrotic cut surface. Also received in the same container is a 2.1 x 1.5 x 0.8 cm aggregate of friable granular gray-tan to pink apparent lesional tissue. Also received in the same container are two tissue cassettes each labeled " ". Representative sections are submitted labeled as follows: A - anterior cervix; B - posterior cervix; C - lower uterine segment shaved posterior serosa; D-F - anterior endomyometrium; G-K - posterior endomyometrium; L-M - left lateral endomyometrium; N-O - right lateral endomyometrium; P-S - fundic endomyometrium; T - left parametrium; U - right parametrium; V - left adnexa; W - right adnexa; X - separate lesional tissue fragments.

Microscopic Description:
See diagnosis.

Final Diagnosis

Lymph nodes, right pelvic area, regional dissection:
Number of lymph nodes identified: 5
Number of lymph nodes demonstrating metastatic malignancy: 0 (0/5)

Lymph nodes, left pelvic area, regional dissection:
Number of lymph nodes identified: 5
Number of lymph nodes containing metastatic malignancy: 0 (0/5)

Lymph nodes, right aortic area, regional dissection:
Number of lymph nodes identified: 2
Number of lymph nodes containing metastatic malignancy: 0 (0/2)

Lymph nodes, left aortic area, regional dissection:
Number of lymph nodes identified: 7
Number of lymph nodes containing metastatic malignancy: 0 (0/7)

Uterus, bilateral fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy:
Endometrial adenocarcinoma.

page 2 of 4

[page 3 of 4]
Tumor characteristics:

Histologic type: Endometrioid endometrial adenocarcinoma with serous areas.

Histologic grade: Grade 3

Tumor site: Entire endometrial cavity

Tumor size: Approximately 8.8 x 3.5 cm as measured grossly

Myometrial invasion: Focally present, invading approximately 0.3 cm into a 1.6 cm thick

myometrium (much less than 50% of the myometrial thickness)

Extent of tumor: Extends into lower uterine segment, but does not involve endocervical mucosa or stroma.

Involvement of other organs: Not identified

Lymphovascular space invasion: Present (see comment)

Parametrial tissues: Right and left are both negative

Other:

Ectocervix:

Negative for viral changes, dysplasia and malignancy.

Endocervix:

Intense chronic endocervicitis.

Negative for glandular dysplasia.

Endometrium:

See above.

Myometrium:

See above.

Serosa:

Negative for endometriosis and malignancy.

Ovaries:

Negative for endometriosis and malignancy.

Fallopian tubes:

Negative for endometriosis and malignancy.

Stage:

pT1a (FIGO IA) N0 PAS 9

CPT:

Comments

The amount of carcinoma is impressive. Much of this is present as sheets of tumor and overt back-to-back oval and tubular glands along with nondescript areas of cribriforming. There are areas of (benign) squamoid metaplasia, as expected in endometrioid forms of endometrial adenocarcinoma. Because of the findings noted below, the grade assigned is a 3.

In addition, within the myometrium there are multiple areas of lymphovascular space invasion identified, best seen in sections 5J and K. These are discrete nests of tumor surrounded by what appear to be endothelial-lined spaces. One of these nests is within vessels located approximately 5 mm (0.5 cm) from the serosal surface.

Finally, in order to more fully assess the presence of serous differentiation, immunohistochemical stains are performed on block 5O, with the following results:

P53: positive (extensively).

ER: positive

WT1: negative

The features are most consistent with an endometrioid adenocarcinoma with presence of serous differentiation.

At my request, the case has also been reviewed by Dr. [REDACTED]

page 3 of 4

[page 4 of 4]
who concurs with the findings.

This test has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

page 4 of 4

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file 63212fae-d709-4243-a573-407ee78a8fd9 (TCGA-AJ-A3EK.F153EAC2-7347-4CEF-916A-995C7BB8B0F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).